Surgical pathology report (de-identified scan), TCGA case TCGA-HD-8634, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-8634-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis

Left partial glossectomy, posterior and inferior shave margins, with frozen section:
No tumor identified.

Left partial glossectomy, anterior, superior, and deep shave margins, with frozen section:
No tumor identified.

Left partial glossectomy:
Moderately differentiated endophytic squamous cell carcinoma, 1 cm, invasive to a depth of 0.5 cm.
The final margins of resection are free of involvement.
Definite angiolymphatic invasion is not identified.

Sentinel lymph node #1 (left upper deep cervical):
No metastatic squamous cell carcinoma identified on routine H&E stains.
Immunoperoxidase stain for pankeratin is negative for infiltrating squamous cell carcinoma.

Sentinel lymph node #2 (left upper deep cervical):
No metastatic squamous cell carcinoma identified on routine H&E stains.
Immunoperoxidase stain for pankeratin is negative for infiltrating squamous cell carcinoma.

Lymph node #3, left level 3:
No metastatic squamous cell carcinoma identified on routine H&E stains.
Immunoperoxidase stain for pankeratin is negative for infiltrating squamous cell carcinoma.

Lymph node #4, left level 1A:
No metastatic squamous cell carcinoma identified on routine H&E stains.
Immunoperoxidase stain for pankeratin is negative for infiltrating squamous cell carcinoma.

AJCC pathologic stage: T1,N0.

[page 2 of 2]
Clinical Information

Left tongue cancer.

Frozen Section Diagnosis

Time out: None given

FSA1: Posterior and inferior margins, shaved: No tumor noted.

FSA2: Anterior, superior, and deep margins, shaved: No tumor noted.

Gross: Left partial glossectomy, lateral portion of tongue measuring 3 x 2.5 x 1 cm with 1 cm diameter white lesion. Inked as follows – Red = posterior, green = anterior, blue = inferior, black = superior, orange = deep. Margin shaved. Grossly free. NTF

Gross Description

"FSA1." All frozen section control tissue is submitted in cassette "FSA1,".

"FSA2" All frozen section control tissue is submitted in cassette "FSA2,".

"NFSA." The specimen consists of a 3 x 2.5 x 1 cm partial glossectomy specimen which has been oriented by the surgeon and inked by the pathologist as follows: Posterior = red, anterior = green, inferior = blue, superior = black, and deep = orange. There is a 1.2 x 1 cm firm tan-white mass which comes to within 0.5 cm of the superior margin, 0.5 cm of the anterior margin, 1 cm of the posterior margin, 0.5 cm of the inferior margin. The lesion extends to a depth of 0.4 cm and comes to within 0.9 cm of the deep margin. All surgical margins have previously been submitted for frozen section. Representative sections of the lesion will be submitted in cassettes "A1-A3,".

"B, Sentinel #1 left upper deep cervical." The specimen consists of a 1.8 x 0.9 x 0.7 cm red-gray lymph node. "B," 3p, all.

"C, Sentinel #2 left upper deep cervical." The specimen consists of a 1 x 0.9 x 0.5 cm gray-pink lymph node. "C," 2p, all.

"D, Lymph node #3 left level 3." The specimen consists of a 1.5 x 0.9 x 0.5 cm gray-pink lymph node. "D," 2p, all.

"E, Lymph node #4 left level 1A." The specimen consists of a 1.3 x 1 x 0.6 cm gray-pink lymph node. "E," 2p, all. (cmm

Performing Lab

Source: NCI Genomic Data Commons file 71395afc-8752-4ca0-823e-c498ebd72f41 (TCGA-HD-8634.A40B36E3-AA93-4E8B-AA5F-C22017D613D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).